Gene-level copy-number profile of tumor specimen TCGA-CN-A49B-01A from TCGA case TCGA-CN-A49B, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 71.6 years (26,155 days).
Specimen TCGA-CN-A49B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.922b3d2d-4a56-4fcc-a8cb-944556fb3241.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CN-A49B-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/75159d1e-a34d-4297-8940-a8ca09d33991

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 922; copy number 2: 5,694; copy number 3: 9,125; copy number 4: 35,362; copy number 5: 4,293; copy number 6: 3,387; copy number 7: 45; copy number 8: 189; copy number 10: 281; copy number 13: 34; copy number 14: 25; copy number 15: 2; copy number 16: 117; copy number 18: 251; copy number 19: 33; copy number 22: 36; copy number 27: 7; copy number 77: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CN-A49B-01A-31D-A24C-01): tumor purity 0.66, ploidy 2.09, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 800 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:88,420,167–88,756,725, 1 gene, copy number 18 (within-gene range 4–18): AC002069.2.
- chr7:88,512,029–89,338,528, 7 genes, copy number 15–18 (within-gene range 3–18): AC002069.3, KPNA2P2, PQLC1P1, EEF1A1P28, AC002127.1, ZNF804B, TEX47.
- chr7:91,311,368–108,130,361, 419 genes, copy number 10–19 (within-gene range 10–20) (broad region; genes not listed).
- chr11:68,754,620–71,639,769, 81 genes, copy number 14–22 (broad region; genes not listed).
- chr12:56,923,133–70,243,379, 292 genes, copy number 16–77 (within-gene range 3–77) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
